Gene-level copy-number profile of tumor specimen TCGA-PQ-A6FN-01A from TCGA case TCGA-PQ-A6FN, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 78.2 years (28,546 days).
Specimen TCGA-PQ-A6FN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.9dbcb7c1-0203-4d32-8bfc-32536634bf1e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PQ-A6FN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af62627e-f790-418e-9000-58b8096cc7d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 15,375; copy number 2: 35,178; copy number 3: 8,955; copy number 5: 270.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PQ-A6FN-01A-11D-A31K-01): tumor purity 0.22, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:12,859,101–15,427,914, 29 genes (within-gene range 0–3): AC007370.2, AC007370.1, U6, HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1, LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1, LINC00504, MTND2P31, SNORA63, CPEB2-DT, CPEB2, C1QTNF7-AS1, RN7SKP170.
- chr12:16,513,445–17,167,790, 11 genes: AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 270 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:20,017,014–23,328,493, 270 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,872. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
